TCGA case TCGA-44-7660 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a534b96b-1665-444a-9308-e610f2f0e510

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.8 years (26,594 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant PRAME Protein Plus AS15 Adjuvant GSK2302025A; Days to treatment start: 78 days; Days to treatment end: 141 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 73.5 years (26,847 days); Days to diagnosis: 253 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (6 entries)
- Days to follow up: 162 days; Disease response: Tumor Free.
- Day 253 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 253 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 325 days; Disease response: With Tumor.
- Days to follow up: 592 days (1.6 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.
- Karnofsky performance status: 70; Timepoint: Other.

Other clinical attributes
- DLCO (% of predicted): 80; FEV1/FVC after bronchodilator (%): 95; FEV1/FVC before bronchodilator (%): 92; FEV1 after bronchodilator (% of reference): 94; FEV1 before bronchodilator (% of reference): 83.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 124; Tobacco smoking onset year: 1949.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-7660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.7.
  Slide TCGA-44-7660-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-44-7660-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-44-7660-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-7660-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-7660-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; Pulmonary function test indicator: Yes.
- Drug treatment: Pharmaceutical therapy drug name: recPRAME+AS15 ASCI; Clinical trial drug classification: Asci; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 592 days; disease-specific survival: no event (censored), 592 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 253 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-7660-01A-11D-2062-01): tumor purity 0.58, ploidy 3.25, whole-genome doublings 1.
